CCDI case PBBTYZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/5d88868f-cb66-4106-9979-8583c3a776cc

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Spindle cell rhabdomyosarcoma: ICD-O-3 morphology code: 8912/3; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 2.0 years (744 days).

Biospecimens (3 samples)
- Sample 0DGWO7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DGWOC: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGWOJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
